Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A2NE, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A2NE-06A (Metastatic).

Collection Date:

FINAL DIAGNOSIS:

1. ILEUM:

- A. ~~METASTATIC MALIGNANT MELANOMA, MULTIFOCALLY INVOLVING THE MUSCULARIS AND SUBSEROA OF THE ILEUM~~
- B. FOCAL INVOLVEMENT OF LAMINA PROPRIA AND MUCOSA IS ALSO SEEN.
- C. MULTIFOCAL SOFT TISSUE INVOLVEMENT NOTED.

2. GREATER OMENTAL TUMOR:

OMENTAL TISSUE INVOLVED BY MALIGNANT MELANOMA NOTED.

ICD-0-3

Melanoma, NOS 8720/3

Site: ileum, soft tissue C49.9

hw
8/19/11

Source: NCI Genomic Data Commons file a7bc1ec3-9a24-455e-81d8-d8575fa5dab0 (TCGA-ER-A2NE.26929BC1-E319-4104-9B08-0B90EACE2022.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).